Somatic mutation profile of tumor specimen MBCProject_1151_T1_WES (aliquot MBCProject_1151_T1_WES_1) from CMI case MBCProject_1151, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 41.7 years (15,244 days).
Specimen MBCProject_1151_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bec2a133-3a29-4b77-9bd8-78c62581e411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1151_SALIVA (Saliva), aliquot MBCProject_1151_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19a181d3-7bdc-46e1-befb-1cf4f2d0cdbd

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Intron 2, Splice Site 2, 5'UTR 1, 5'Flank 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD2 | c.482C>T p.A161V (on ENST00000315906 / NM_001145400.2; = p.A233V on NM_139174.4) | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs577228328, COSV51893583; called by muse, mutect2, varscan2
- CUL4B | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV60686213; called by muse, mutect2, varscan2
- CYP39A1 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.388); catalogued as rs964967671, COSV99242421; called by muse, mutect2, varscan2
- FBH1 | c.2107C>T p.R703W (on ENST00000362091 / NM_178150.3; = p.R754W on NM_032807.4) | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193921138, COSV62981738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHOD3 | c.1849G>A p.E617K (on ENST00000359247 / NM_001281739.3; = p.E634K on NM_025135.5) | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as rs1044726015, COSV57182747; called by muse, mutect2, varscan2
- IGHV3-74 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as rs776784401; called by muse, mutect2, varscan2
- IRS2 | c.3653G>A p.R1218Q | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1438145504; called by muse, mutect2, varscan2
- KCNU1 | c.1611G>T p.M537I | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101299364; called by muse, mutect2
- MB21D2 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.699); catalogued as rs1284618099; called by muse, mutect2, varscan2
- PLEKHA6 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs779692794; called by muse, mutect2
- SLCO4A1 | c.1977G>T p.Q659H | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1415742835; called by muse, mutect2
- SMARCA2 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1471482709, CM1311957, COSV61804436; called by muse, mutect2, varscan2
- SPEF2 | c.5378C>T p.P1793L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100289234; called by muse, mutect2
- TRARG1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200319809, COSV61562711; called by muse, mutect2, varscan2
- TUBGCP6 | c.4876G>A p.G1626S | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.352); catalogued as rs201575861; called by muse, mutect2, varscan2
- ATXN7L2 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- CHRNA6 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- FKBP3 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, varscan2
- FOXN1 | c.258del p.G87Afs*215 | Frame Shift Del (DEL) | VAF 29/224 reads (13%) | called by mutect2, pindel, varscan2
- GALK1 | c.838C>G p.H280D | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GID8 | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2
- KHSRP | c.531_547+8del p.X177_splice | Splice Site (DEL) | VAF 27/127 reads (21%) | called by mutect2, pindel, varscan2
- KLHL30 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- LIG3 | c.2568G>T p.E856D | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.345); called by muse, mutect2
- MAPKAP1 | c.1285C>T p.P429S (on ENST00000265960 / NM_001006617.3; = p.P393S on NM_024117.3) | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RXRA | c.430+2T>C p.X144_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- TIAM2 | c.4424T>C p.I1475T (on ENST00000529824; = p.I1446T on NM_012454.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2
- ZNF350 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ATP13A2 | c.792C>T p.F264= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs1182566843; called by muse, mutect2, varscan2
- DRC3 | c.12G>A p.P4= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs373716910; called by muse, mutect2, varscan2
- INTS1 | c.5148G>A p.P1716= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as rs755594723, COSV67177692; called by muse, mutect2, varscan2
- IRX4 | c.114G>C p.G38= | Silent (SNP) | VAF 49/213 reads (23%) | called by muse, mutect2, varscan2
- MAGEL2 | c.3051G>A p.L1017= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- OVGP1 | c.72C>A p.L24= | Silent (SNP) | VAF 29/324 reads (9%) | catalogued as COSV63859203; called by muse, mutect2
- PCDHB12 | c.690G>A p.V230= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV53400909; called by muse, mutect2, varscan2
- PKP3 | c.2103C>A p.I701= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- PTCHD3 | c.411C>T p.H137= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs773218119, COSV71256805; called by muse, mutect2, varscan2
- ZNF561 | c.702C>G p.V234= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- KIF3C | c.2007-8261A>G | Intron (SNP) | VAF 3/23 reads (13%) | catalogued as rs1284857150; called by muse, mutect2
- NLRP2 | c.281-393A>G | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs752108162; called by muse, varscan2
- RNA5S17 | chr1:228650575 G>A | 5'Flank (SNP) | VAF 38/308 reads (12%) | catalogued as rs1408144972; called by muse, mutect2, varscan2
- RSPO1 | c.-284G>T | 5'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.691G>T | RNA (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
